Somatic mutation profile of tumor specimen 0DIMX4 from CCDI case PBBVXM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,261 days).
Specimen 0DIMX4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfb95d15-1ed8-42b7-8090-bf620acd7493.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c812182-e9c5-4b30-885e-1aaff35811ed

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Nonsense Mutation 1, Silent 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 249/1662 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- USP26 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 223/828 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs755327016, COSV100896720; called by muse, mutect2, varscan2
- OR2A42 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 150/841 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- SOX10 | c.517_522dup p.Y173_Q174dup | In Frame Ins (INS) | VAF 78/604 reads (13%) | called by mutect2, varscan2
- TAOK1 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 181/1212 reads (15%) | called by muse, mutect2, varscan2
- RIPK4 | c.1725C>T p.N575= (on ENST00000352483; = p.N527= on NM_020639.3) | Silent (SNP) | VAF 27/378 reads (7%) | catalogued as rs143300354; called by muse, mutect2
- COL6A3 | c.7668+16G>A | Intron (SNP) | VAF 49/338 reads (14%) | catalogued as rs746169209, COSV55093841; called by muse, mutect2, varscan2
- MON2 | c.4195-99G>C | Intron (SNP) | VAF 14/371 reads (4%) | called by muse, mutect2
